Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3594, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3594-01A (Primary Tumor).

Diagnosis/diagnoses:

Resected colon and rectum show tumor-free oral, aboral and perirectal resection margins, with an ulcerated, moderately differentiated, abundant mucus-forming adenocarcinoma with infiltration of the perimuscular fatty tissue (G2, pT3, pN0 0/25 L0 V0 R0, distance of the tumor to the perirectal resection margin is at least 1.6 cm) and with a recent ulcerous mucosal defect located directly orally of the carcinoma (with possible status post endoscopic excision of an adenoma).

Source: NCI Genomic Data Commons file a89b4fa8-3e94-4b1c-a4c6-a24c30ca7c4f (TCGA-AG-3594.831B97AF-F890-4E89-9918-287945D18EE3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).